Somatic mutation profile of tumor specimen 0DNKZF from CCDI case PBCBSI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Endocervix; Age at diagnosis: 22.0 years (8,038 days).
Specimen 0DNKZF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c8f79499-401b-479f-8e8f-098e894adb7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNKZC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ea2beae-e606-4e5f-9b2b-de641d859d1d

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.7306G>A p.V2436I (on ENST00000272895 / NM_173076.3; = p.V2118I on NM_015657.3) | Missense Mutation (SNP) | VAF 153/1664 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs771756451; called by muse, mutect2
- ART4 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 197/906 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs764804390; called by muse, mutect2, varscan2
- RNF213 | c.13691G>A p.R4564Q | Missense Mutation (SNP) | VAF 116/1240 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs371619739; called by muse, mutect2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 36/622 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2
- CFHR4 | c.784C>A p.P262T (on ENST00000367416 / NM_001201551.2; = p.P263T on NM_001201550.3) | Missense Mutation (SNP) | VAF 101/841 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MYO6 | c.3073A>T p.S1025C | Missense Mutation (SNP) | VAF 141/1099 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEB | c.8498A>G p.K2833R | Missense Mutation (SNP) | VAF 103/876 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.274); called by muse, varscan2
- NEK10 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 160/751 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- PHKA1 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 152/804 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLEKHS1 | c.57T>A p.D19E (on ENST00000369310 / NM_182601.1; = p.D25E on NM_024889.5) | Missense Mutation (SNP) | VAF 175/1534 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- RGR | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 252/968 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC25A46 | c.304G>C p.G102R | Missense Mutation (SNP) | VAF 148/1813 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- TOMM7 | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 186/860 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF132 | c.1652C>A p.A551D | Missense Mutation (SNP) | VAF 189/824 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- GLUD2 | c.1158G>A p.K386= | Silent (SNP) | VAF 132/1227 reads (11%) | called by muse, mutect2, varscan2
- RPTOR | c.2304C>T p.T768= | Silent (SNP) | VAF 34/896 reads (4%) | catalogued as COSV60805577; called by muse, mutect2
- VSTM1 | c.603C>A p.P201= | Silent (SNP) | VAF 103/404 reads (25%) | catalogued as COSV58076607; called by muse, mutect2, varscan2
- HRK | c.*32G>A | 3'UTR (SNP) | VAF 78/303 reads (26%) | catalogued as rs927595448; called by muse, varscan2
- SLC22A20P | n.926G>T | RNA (SNP) | VAF 188/990 reads (19%) | called by muse, mutect2, varscan2
